Somatic mutation profile of tumor specimen BA2992D (aliquot aq-BA2992D) from BEATAML1.0 case 2348, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute myeloid leukemia, CBF-beta/MYH11; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.3 years (19,085 days).
Specimen BA2992D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b5bc7eb-09ab-41ff-afdb-0752cdadb377.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2927D (Solid Tissue Normal), aliquot aq-BA2927D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c67198a-5e79-417f-941a-a2c2a09f311d

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 2, Missense Mutation 2, Intron 1, 3'UTR 1, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AK7 | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 86/179 reads (48%) | catalogued as rs762440219; called by muse, mutect2, varscan2
- OR52H1 | c.787G>A p.A263T (on ENST00000322653; = p.A269T on NM_001005289.1) | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.182); catalogued as rs761950199, COSV59504820; called by muse, mutect2, varscan2
- TCHH | c.4777C>T p.Q1593* | Nonsense Mutation (SNP) | VAF 14/428 reads (3%) | catalogued as rs1038879013; called by muse, mutect2
- CCT7 | c.1196C>A p.A399D | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- MEGF8 | c.6588C>T p.H2196= (on ENST00000251268 / NM_001271938.2; = p.H2129= on NM_001410.3) | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as rs751105144, COSV52084123; ClinVar: likely benign; called by muse, mutect2, varscan2
- BRCA1 | c.*715G>T | 3'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- MIR374A | n.33G>A | RNA (SNP) | VAF 46/121 reads (38%) | catalogued as rs1360532268; called by muse, mutect2, varscan2
- WDR90 | c.1437+16C>A | Intron (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
